Surgical pathology report (de-identified scan), TCGA case TCGA-3E-AAAY, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Columbia University, specimen TCGA-3E-AAAY-01A (Primary Tumor).

[page 1 of 3]
Name: [REDACTED]
MRN: [REDACTED]
D.O.B. (Age: [REDACTED])
Sex: M
Location:

Path No.: [REDACTED]
Date Obtained:
Date Received:
Physician:

SURGICAL PATHOLOGY

SPECIMEN:

A: Pancreas and duodenum, pancreatoduodenectomy
B: Pancreas, body, pancreatectomy
C: Stent, removal

ICD-O-3
Adenocarcinoma, duct NOS 8500/3
Site: Pancreas body C25.1
706/13/14

DIAGNOSIS(ES):

A. Pancreas and duodenum, pancreatoduodenectomy:

1. Adenocarcinoma of pancreas, infiltrating pancreas and multifocally peripancreatic adipose tissue, moderately differentiated, with metastasis to 5 of 19 peripancreatic lymph nodes, not involving duodenum, on pancreatic surgical margin (see final pancreatic surgical margin status in part "B"), on anterior peripancreatic surface and within 0.1 mm of posterior pancreatic surface.
2. Common bile duct, no carcinoma identified on margin.
3. Dysplasia, mild, focal, in distal common bile duct in ampullary region.
4. PanIN 1A, 1B and 2 head of pancreas.
5. Pancreas with foci of atrophy and chronic inflammation.

B. Pancreas, body, pancreatectomy:

1. Adenocarcinoma, moderately to poorly-differentiated, of pancreas with extension to peripancreatic adipose tissue, not identified on new pancreatic surgical margin or anterior or posterior margins.
2. Chronic lymphadenitis of 4 peripancreatic lymph nodes, no tumor seen in lymph nodes.
3. Pancreas with focal atrophy and chronic pancreatitis.
4. PanIN 1B.

C. Stent, removal:

(Gross) Stent (removal).

Date Dictated:

CLINICAL INFORMATION: Head of pancreas and duodenum, patient's old stent, Whipple procedure.

GROSS DESCRIPTION:

The specimen is received in 3 parts.

Per TSS, stent is not TCGA tumor
or treatment related. BGR

Part A is received fresh from the operating room for frozen section diagnosis in a container labeled with the patient's name and "head of pancreas and duodenum". It consists of an en bloc resection of duodenum and the head of the pancreas measuring 14.5 x 9.5 x 5.8 cm overall. The proximal stapled margin measures 10.8 cm in circumference. The duodenal segment measures 14.5 cm with a distal margin measuring 10.8 cm in circumference. The portion of pancreas measures 7.8 x 5.8 x 4.6 cm. A palpable mass measuring approximately 1.5 cm is noted 0.3 cm from the pancreatic surgical margin. The pancreatic surgical margin, which occupies an area of 3.0 x 1.5 cm is marked with two

[page 2 of 3]
long black sutures by the surgeon and is submitted as AFS1, the false margin is inked yellow. The cut surface of the pancreas is yellow. Dilated pancreatic ducts are not noted at the margin. The common bile duct margin is submitted en face as AFS2. AFS 3 pancreatic mass. The common bile duct is probed into the ampulla and appears unobstructed. The proximal and distal duodenal margins are inked black. The duodenum and pancreas are serially sectioned from proximal to distal revealing a firm off-white poorly circumscribed mass abutting the bile duct in the head of the pancreas and measuring approximately 1.5 cm. The mass abuts the anterior surface of the pancreas but does not invade into the duodenal wall. The duodenal mucosa is unremarkable. Lymph nodes are identified in the peripancreatic and duodenal fat. Representative sections are submitted in 20 cassettes labeled A1-A20. Anterior surface inked green, posterior surface of pancreas black.

LEGEND:

AFS1 = True pancreatic
AFS2 = common bile duct margin
AFS3 = pancreatic mass
A1 = New (false) pancreatic margin
A2 = New (false) common bile duct margin
A3 = Distal duodenal margin
A4 = Proximal duodenal margin
A5 = Random duodenum
A6 = Mass to anterior surface
A7 = Mass to anterior surface and bile duct
A8-10 = Mass to posterior surface
A11 = ampulla
A12-20 = fat for lymph nodes

Part B is received fresh from the operating room for frozen section diagnosis in a container labeled with the patient's name and "body of pancreas blue suture on new margin". It consists of one piece of red to yellow soft tissue measuring 3.1 x 1.5 x 1.5 cm. A suture marks the true margin, which is submitted en face as BFS1-2. The false margin is inked blue and the opposite margin yellow. The remaining surfaces are inked black. The specimen is submitted in toto in 5 cassettes labeled BFS1-2 and B1-3.

LEGEND

BFS1 = New pancreatic margin, pancreatic duct
BFS2 = New pancreatic margin
B1-3 = remaining tissue

Part C is received fresh in a container labeled with the patient's name and "patient's old stent". It consists of one piece of a blue rubber tube measuring 8.8 x 0.4 x 0.4 cm. The container is marked "SAVE". GROSS ONLY.

INTRAOPERATIVE CONSULTATION:

AFS1: Pancreatic margin with invasive carcinoma.
AFS2: Common bile duct margin, no carcinoma identified.
AFS3: (Mass) Multifocal in situ carcinoma and foci highly suspicious for invasive carcinoma.
BFS1 + BFS2 = New pancreatic margin, no carcinoma seen. PanIN1b and ? low-grade IPMN identified.
Performed by: Resident:
Interpreted by: Attending:

MICROSCOPIC DESCRIPTION:

- I. TYPE OF SPECIMEN: Pylorus sparing Whipple resection
- II. ATTACHED VESSELS: None
- III. TYPE OF NEOPLASM: Ductal adenocarcinoma
- IV. HISTOLOGIC GRADE: G2/G3: Moderately to Poorly differentiated

[page 3 of 3]
- V. TUMOR SITE: Pancreatic head and body
- VI. TUMOR SIZE: Cannot be determined > 3 cm
- VII. OTHER ORGANS RESECTED: None
- VIII. VENOUS/LYMPHATIC INVASION: Indeterminate
- IX. PERINEURAL INVASION: Present
- X. ADDITIONAL PATHOLOGIC FINDINGS: Pancreatic intraepithelial neoplasia (highest grade PanIN 1B, 2)
Chronic pancreatitis
Margin: Posterior retroperitoneal (radial) margin: posterior surface of pancreas -cancer < 0.1 mm from surface
Not on pancreatic surgical margin
Not on common bile duct
On anterior pancreatic surface margin
- XII. PATHOLOGIC STAGING (pTNM): **Reflects staging only of the current specimen. Ultimate staging responsibility rests with the primary physician.**
- pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery
pMX: Cannot be assessed
Number examined: 23
Number involved: 5
pMX: Cannot be assessed

COMMENT(S):

Key slides: "AFS1", "A6", "A7", "A8", "A10", "B2".

This report has been reviewed electronically and signed on

Interpreted by: Attending:

Case Resident:

The diagnosis was rendered by the attending pathologist.

Note: Immunochemistry testing performed at _____ was developed and its performance characteristics determined by the _____.
These tests were interpreted in conjunction with external positive and internal negative controls, unless otherwise noted.
FDA: This test is used for clinical purposes only. It should not be regarded as investigational or for research.

Source: NCI Genomic Data Commons file b1ca1a4c-c2a8-45ff-bff1-3316a7317e64 (TCGA-3E-AAAY.AD52C918-01E3-4EE0-8207-79A17EA7F715.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).